Somatic mutation profile of tumor specimen TCGA-DV-A4W0-05A (aliquot TCGA-DV-A4W0-05A-11D-A25V-10) from TCGA case TCGA-DV-A4W0, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 55.0 years (20,101 days).
Specimen TCGA-DV-A4W0-05A: Sample type: Additional - New Primary; Tissue type: Tumor; Tumor descriptor: New Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 5cffdd02-e37c-493d-9a15-ac615bf3a7ce.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-DV-A4W0-10A (Blood Derived Normal), aliquot TCGA-DV-A4W0-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/d791f2e6-c3df-492f-9d4b-ac2c3c4a72d3

The open-access MAF lists 29 somatic variants for this specimen: 23 protein-altering or splice-affecting, 6 silent.
By variant classification: Missense Mutation 18, Silent 6, Frame Shift Del 3, Nonsense Mutation 2.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- CCDC24 | c.167C>T p.S56F | Missense Mutation (SNP) | VAF 96/255 reads (38%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as rs765556097, COSV100530795; called by muse, mutect2, varscan2
- CCNB1 | c.634G>A p.V212I | Missense Mutation (SNP) | VAF 33/132 reads (25%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.495); catalogued as rs768278048; called by muse, mutect2, varscan2
- CLEC2B | c.302G>T p.R101L | Missense Mutation (SNP) | VAF 33/95 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0); catalogued as COSV99946979; called by muse, mutect2, varscan2
- DLG5 | c.4543C>T p.H1515Y | Missense Mutation (SNP) | VAF 34/379 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.187); catalogued as COSV100967508; called by muse, mutect2
- DNTTIP2 | c.1858C>T p.P620S | Missense Mutation (SNP) | VAF 6/56 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs755451451, COSV100785169; called by muse, mutect2, varscan2
- DYNC2I1 | c.2886G>T p.W962C | Missense Mutation (SNP) | VAF 9/42 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101337683, COSV68105308; called by muse, mutect2, varscan2
- GANAB | c.2133G>T p.W711C | Missense Mutation (SNP) | VAF 67/179 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV100648051; called by muse, mutect2, varscan2
- KIF19 | c.485T>C p.L162P | Missense Mutation (SNP) | VAF 34/82 reads (41%) | SIFT deleterious (0); PolyPhen possibly damaging (0.798); catalogued as COSV100739077; called by muse, mutect2, varscan2
- KRT33B | c.884C>G p.S295C | Missense Mutation (SNP) | VAF 15/68 reads (22%) | SIFT tolerated (0.21); PolyPhen probably damaging (0.992); catalogued as COSV99290641; called by muse, mutect2, varscan2
- LEO1 | c.1432G>A p.G478S | Missense Mutation (SNP) | VAF 22/92 reads (24%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV100166517; called by muse, mutect2, varscan2
- MKRN3 | c.46G>A p.A16T | Missense Mutation (SNP) | VAF 24/48 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.698); catalogued as COSV58810992; called by muse, varscan2
- MROH5 | c.41C>T p.P14L | Missense Mutation (SNP) | VAF 23/52 reads (44%) | SIFT tolerated, low confidence (0.18); PolyPhen benign (0.003); catalogued as rs199532269; called by muse, mutect2, varscan2
- NISCH | c.2900C>A p.A967D | Missense Mutation (SNP) | VAF 36/73 reads (49%) | SIFT tolerated (0.2); PolyPhen benign (0.425); catalogued as COSV61898530; called by muse, mutect2, varscan2
- NLRP13 | c.1329C>G p.Y443* | Nonsense Mutation (SNP) | VAF 77/178 reads (43%) | catalogued as COSV61619711, COSV61622587; called by muse, mutect2, varscan2
- P2RY13 | c.829C>T p.P277S | Missense Mutation (SNP) | VAF 11/139 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV99853287; called by muse, mutect2
- SEC24B | c.2645A>G p.K882R | Missense Mutation (SNP) | VAF 8/88 reads (9%) | SIFT tolerated (0.55); PolyPhen benign (0.066); catalogued as rs1464558183, COSV54498657; called by muse, mutect2, varscan2
- SPSB2 | c.692G>A p.S231N | Missense Mutation (SNP) | VAF 28/73 reads (38%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.871); catalogued as rs782544484, COSV99222903; called by muse, mutect2, varscan2
- ZNF106 | c.5376G>C p.M1792I | Missense Mutation (SNP) | VAF 8/20 reads (40%) | SIFT deleterious (0.02); PolyPhen benign (0.043); catalogued as COSV99782645; called by muse, mutect2, varscan2
- ZNF280B | c.250C>A p.R84S | Missense Mutation (SNP) | VAF 8/143 reads (6%) | SIFT tolerated (0.83); PolyPhen benign (0.003); catalogued as COSV100840315; called by muse, mutect2
- ZRANB3 | c.660C>A p.Y220* | Nonsense Mutation (SNP) | VAF 29/75 reads (39%) | catalogued as COSV99923735; called by muse, mutect2, varscan2
- ESYT1 | c.1903del p.C635Vfs*20 | Frame Shift Del (DEL) | VAF 43/134 reads (32%) | called by mutect2, pindel, varscan2
- RPP30 | c.144del p.I48Mfs*5 | Frame Shift Del (DEL) | VAF 7/81 reads (9%) | called by mutect2, pindel
- RPS6KL1 | c.1643del p.V548Gfs*79 | Frame Shift Del (DEL) | VAF 18/169 reads (11%) | called by mutect2, pindel, varscan2
- ASPH | c.21C>T p.A7= | Silent (SNP) | VAF 6/16 reads (38%) | catalogued as COSV100727588; called by muse, mutect2
- DACH1 | c.1485C>A p.A495= (on ENST00000619232 / NM_001366712.1; = p.A443= on NM_080759.6) | Silent (SNP) | VAF 35/109 reads (32%) | catalogued as rs534663252, COSV100498437; called by muse, mutect2, varscan2
- EBF1 | c.834G>A p.A278= | Silent (SNP) | VAF 45/135 reads (33%) | catalogued as COSV58165854; called by muse, mutect2, varscan2
- ELOA2 | c.1191A>G p.K397= | Silent (SNP) | VAF 49/117 reads (42%) | catalogued as COSV99796713; called by muse, mutect2, varscan2
- NR4A2 | c.72C>T p.Y24= | Silent (SNP) | VAF 20/181 reads (11%) | catalogued as COSV100277202; called by muse, mutect2, varscan2
- UROS | c.453G>T p.L151= | Silent (SNP) | VAF 37/108 reads (34%) | catalogued as rs147782343; called by muse, mutect2, varscan2
